Somatic mutation profile of tumor specimen 0DDPQ0 from CCDI case PBBNRL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 2.2 years (791 days).
Specimen 0DDPQ0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd3b1af7-d2f9-40cb-b569-38385f4173b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDPQ1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50593f2c-8a94-4dd1-b04a-28dcb40e9f88

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, RNA 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.2428C>T p.R810* | Nonsense Mutation (SNP) | VAF 43/371 reads (12%) | catalogued as rs1555918056, CM095797, COSV60703357; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RPUSD4 | c.994C>G p.L332V | Missense Mutation (SNP) | VAF 36/513 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as COSV100028678; called by muse, mutect2
- ABCC2 | c.2396T>C p.I799T | Missense Mutation (SNP) | VAF 80/573 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- ATP2B2 | c.3178G>C p.G1060R (on ENST00000352432; = p.G1026R on NM_001683.5) | Missense Mutation (SNP) | VAF 97/361 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- PITRM1 | c.1305G>C p.Q435H | Missense Mutation (SNP) | VAF 60/499 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- SARAF | c.74C>G p.A25G | Missense Mutation (SNP) | VAF 40/279 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- ZSWIM2 | c.487T>C p.F163L | Missense Mutation (SNP) | VAF 105/420 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- HAS1 | c.207G>A p.A69= | Silent (SNP) | VAF 59/182 reads (32%) | catalogued as rs1287330855; called by muse, mutect2, varscan2
- TRIM16L | n.1217C>T | RNA (SNP) | VAF 220/526 reads (42%) | catalogued as rs1452518758; called by muse, mutect2, varscan2
